Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7QZ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7QZ-01A (Primary Tumor).

ICD-6-3
Oligodendroglioma grade II 9450/3
Site ~~Brain~~ Brain, Supratentorial NOS C71.0
Path ~~Brain~~ Brain, NOS C71.9

QW 9/27/13

glial tumor of oligodendroglial differentiation
IDH1 R132H mutation present

Diagnosis
oligodendroglioma WHO grade II

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 88766f0c-ff10-4bbc-a150-7e24257c02fd (TCGA-S9-A7QZ.2DBE4A35-E160-47C2-B000-B44DC125BAEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).